Gene-level copy-number profile of specimen HCM-SANG-0552-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0552-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0552-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ae1cd7f-7186-4c64-9bdb-9d07fe4cfd1f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0552-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/9d9afb5d-0a2a-44c2-9c89-ed06b9989dbf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 9; copy number 2: 10,645; copy number 3: 7,329; copy number 4: 35,994; copy number 5: 726; copy number 6: 3,554; copy number 7: 18; copy number 8: 72; copy number 10: 7; copy number 12: 4; copy number 13: 11; copy number 14: 4; copy number 15: 5; copy number 23: 2; copy number 24: 1; copy number 28: 1; copy number 30: 2; copy number 34: 15.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:15,361,393–15,544,294, 8 genes, copy number 10–13: RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:19,789,179–20,995,955, 14 genes, copy number 12–13 (within-gene range 12–14): AL158077.2, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.
- chr16:24,537,693–26,137,685, 30 genes, copy number 14–34: RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
